Gene-level copy-number profile of tumor specimen HCM-BROD-0002-C71-86A from HCMI case HCM-BROD-0002-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,213 days).
Specimen HCM-BROD-0002-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 269fb7bc-9335-49f4-b2c1-a8d7ced9d3bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0002-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/6ff98833-f259-4362-ad90-f5721480a38a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,361; copy number 2: 45,125; copy number 3: 498; copy number 4: 2,926.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,505. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
